Somatic mutation profile of tumor specimen TCGA-16-1045-01B (aliquot TCGA-16-1045-01B-01D-1492-08) from TCGA case TCGA-16-1045, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.8 years (18,195 days).
Specimen TCGA-16-1045-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f73788d-be0e-4777-ad12-3005188ebcea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-1045-10B (Blood Derived Normal), aliquot TCGA-16-1045-10B-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/637c1b5f-db7e-4784-a469-2482a2466874

The open-access MAF lists 84 somatic variants for this specimen: 57 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 22, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 2, RNA 2, Intron 1, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 2096/2298 reads (91%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 70/157 reads (45%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs780890433, COSV66169346; called by muse, mutect2, varscan2
- BRWD1 | c.4832C>A p.S1611* | Nonsense Mutation (SNP) | VAF 97/273 reads (36%) | catalogued as COSV60903520; called by muse, mutect2, varscan2
- C1orf112 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs376679451, COSV53683225; called by muse, mutect2
- CPSF1 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62941753, COSV62942868; called by muse, mutect2, varscan2
- CUX2 | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs756580216, COSV55647710, COSV99919073; called by muse, mutect2, varscan2
- DDC | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63568143; called by muse, mutect2, varscan2
- DOCK10 | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 68/227 reads (30%) | catalogued as COSV51429252; called by muse, mutect2, varscan2
- DRP2 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201693431, COSV65812032; called by muse, mutect2, varscan2
- EBF1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100565050, COSV58196684; called by muse, mutect2, varscan2
- ELMO1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs748062510, COSV60299509; called by muse, mutect2, varscan2
- FAM122A | c.650T>C p.F217S | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV55258817; called by muse, mutect2, varscan2
- FBXO31 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs202184616, COSV61151636; called by muse, mutect2, varscan2
- FLNB | c.6211G>A p.V2071I | Missense Mutation (SNP) | VAF 61/544 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs201831615; called by muse, mutect2, varscan2
- GADL1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 118/383 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV56986676; called by muse, mutect2, varscan2
- HUWE1 | c.4963C>T p.R1655* | Nonsense Mutation (SNP) | VAF 153/546 reads (28%) | catalogued as COSV53365799; called by muse, mutect2, varscan2
- KLF7 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.926); catalogued as rs1231413667, COSV58743962; called by muse, mutect2, varscan2
- LHFPL2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV66713436, COSV66716551; called by muse, mutect2, varscan2
- LONRF3 | c.1723T>A p.F575I (on ENST00000371628 / NM_001031855.3; = p.F534I on NM_024778.5) | Missense Mutation (SNP) | VAF 122/461 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59157248; called by muse, mutect2, varscan2
- LRRC14 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs1337625543, COSV52879975; called by muse, mutect2, varscan2
- LRRC7 | c.1036T>C p.C346R (on ENST00000651989 / NM_001370785.2; = p.C313R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.898); catalogued as rs761863170, COSV50644130; called by muse, mutect2, varscan2
- NAV2 | c.2980G>A p.D994N (on ENST00000396087 / NM_001244963.2; = p.D971N on NM_145117.5) | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60663487; called by muse, mutect2, varscan2
- NFIL3 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV52684863; called by muse, mutect2, varscan2
- OCRL | c.1452C>A p.D484E | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV63982008; called by muse, mutect2, varscan2
- OGT | c.1587C>A p.N529K | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV65482804; called by muse, mutect2, varscan2
- OR10AG1 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV56633688, COSV56635152; called by muse, mutect2, varscan2
- OR1G1 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV61030687; called by muse, mutect2, varscan2
- PCCB | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52448467; called by muse, mutect2, varscan2
- PHLDB2 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1301070338, COSV67316478; called by muse, mutect2, varscan2
- POTEE | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs774016121, COSV58230309; called by muse, varscan2
- PTPRC | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.176); catalogued as rs1288480100, COSV61421267; called by muse, mutect2
- RFX7 | c.2754dup p.S919Qfs*4 (on ENST00000559447 / NM_001368074.1; = p.S1016Qfs*4 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/115 reads (10%) | catalogued as rs753737369; called by mutect2, varscan2
- RUNDC3B | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55964822; called by muse, mutect2, varscan2
- SAGE1 | c.944T>G p.V315G | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV61018612; called by muse, mutect2, varscan2
- SEC23B | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV52724322; called by muse, mutect2, varscan2
- SGMS2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV62989863; called by muse, mutect2
- SLC10A4 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720052; called by muse, mutect2, varscan2
- SLC6A16 | c.1039T>A p.L347M | Missense Mutation (SNP) | VAF 124/409 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60030880; called by muse, mutect2, varscan2
- SLC6A4 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55570078; called by muse, mutect2, varscan2
- SSH1 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58460707; called by muse, mutect2, varscan2
- TDP2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 113/445 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57765845; called by muse, mutect2, varscan2
- TENT5C | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); catalogued as rs773285739, COSV65615907; called by muse, mutect2, varscan2
- TMEM255A | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556019904, COSV59028981; called by muse, mutect2, varscan2
- TNS4 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54188377; called by muse, mutect2, varscan2
- TREML4 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV58386571; called by muse, mutect2, varscan2
- UHRF1BP1 | c.4159G>A p.V1387M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51961038; called by muse, mutect2, varscan2
- UNKL | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780500079, COSV57021462; called by muse, mutect2
- VWF | c.8336C>T p.T2779M | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs374314985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR11 | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV54793676; called by muse, mutect2, varscan2
- WDR74 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1162216436, COSV53682246, COSV99586718; called by muse, mutect2
- XPNPEP2 | c.1107C>T p.H369= | Splice Region (SNP) | VAF 28/226 reads (12%) | catalogued as rs776918670, COSV64370491; called by muse, mutect2, varscan2
- YTHDC1 | c.1711G>T p.E571* (on ENST00000344157 / NM_001031732.4; = p.E553* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 65/227 reads (29%) | catalogued as COSV60009598, COSV60012310; called by muse, mutect2, varscan2
- ZFC3H1 | c.3406A>G p.M1136V | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66436253; called by muse, mutect2, varscan2
- ZP4 | c.399A>T p.L133= | Splice Region (SNP) | VAF 70/615 reads (11%) | catalogued as COSV63913670; called by muse, mutect2, varscan2
- CACNA1E | c.357del p.M120Cfs*67 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.36704del p.L12235Rfs*2 (on ENST00000591111; = p.L4811Rfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.2298G>C p.L766= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV55458965; called by muse, mutect2
- CACNA2D1 | c.3102G>A p.A1034= (on ENST00000356253 / NM_001366867.1; = p.A1022= on NM_000722.4) | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as rs780560452, COSV62389499, COSV62394110; called by muse, mutect2, varscan2
- CEP350 | c.8250A>G p.K2750= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV62610365; called by muse, mutect2, varscan2
- DMBX1 | c.96G>A p.Q32= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV63602662; called by muse, mutect2, varscan2
- ELMO1 | c.1758G>A p.L586= | Silent (SNP) | VAF 19/235 reads (8%) | catalogued as COSV60327125; called by muse, mutect2
- GLUD2 | c.432G>A p.T144= | Silent (SNP) | VAF 33/160 reads (21%) | catalogued as rs772586560, COSV60151620; called by muse, mutect2, varscan2
- GYS2 | c.279C>T p.D93= | Silent (SNP) | VAF 114/372 reads (31%) | catalogued as rs779704436, COSV53926335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL5RA | c.444A>G p.S148= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV56527021; called by muse, mutect2
- KIR3DL1 | c.138T>A p.T46= | Silent (SNP) | VAF 83/291 reads (29%) | called by muse, varscan2
- LRCH4 | c.882C>T p.Y294= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs150987161; called by muse, mutect2, varscan2
- MECOM | c.69C>T p.C23= (on ENST00000468789 / NM_001105078.4; = p.C211= on NM_004991.4) | Silent (SNP) | VAF 84/269 reads (31%) | catalogued as rs188482846, COSV52976360; called by muse, mutect2, varscan2
- MRC2 | c.2562G>A p.T854= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs150592174; called by muse, mutect2, varscan2
- OR51A2 | c.798C>T p.A266= | Silent (SNP) | VAF 53/337 reads (16%) | catalogued as rs1412631339, COSV66748208; called by muse, mutect2, varscan2
- PON1 | c.597T>A p.G199= | Silent (SNP) | VAF 31/230 reads (13%) | catalogued as COSV55934082; called by muse, mutect2, varscan2
- SKOR1 | c.693C>T p.D231= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV58248905; called by muse, mutect2, varscan2
- SLC9A8 | c.1581C>T p.F527= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as rs1441932016, COSV64287043; called by muse, mutect2, varscan2
- TBC1D9 | c.2952G>A p.T984= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs190153862; called by muse, mutect2, varscan2
- TPR | c.1239A>G p.K413= | Silent (SNP) | VAF 66/224 reads (29%) | catalogued as COSV66605445; called by muse, mutect2, varscan2
- TRIM5 | c.540C>T p.N180= | Silent (SNP) | VAF 52/244 reads (21%) | catalogued as rs182373551, COSV59902368; called by muse, mutect2, varscan2
- ZNF140 | c.1122A>G p.Q374= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs780929807, COSV60580136; called by muse, mutect2, varscan2
- ZNF521 | c.1041C>T p.V347= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV64122430, COSV64132370; called by muse, mutect2, varscan2
- ZNF581 | c.48C>T p.S16= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs776646245, COSV54401802, COSV54402830; called by muse, mutect2, varscan2
- AC005863.1 | n.108C>T | RNA (SNP) | VAF 81/215 reads (38%) | catalogued as rs1481053438; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208357 C>T | 5'Flank (SNP) | VAF 103/686 reads (15%) | called by muse, mutect2, varscan2
- GPR35 | c.-452-113C>T | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54387481; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472423 T>C | 3'Flank (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- WASF4P | n.839A>G | RNA (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
